Somatic mutation profile of tumor specimen TCGA-XM-A8RG-01A (aliquot TCGA-XM-A8RG-01A-11D-A423-09) from TCGA case TCGA-XM-A8RG, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type A, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 67.9 years (24,802 days).
Specimen TCGA-XM-A8RG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 488e3f60-941b-4c26-9f0c-c015eb8f08d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-A8RG-10A (Blood Derived Normal), aliquot TCGA-XM-A8RG-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b3695ea-301b-4f7a-873c-3d0c691af013

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 211/594 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- HRAS | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880460, CM158178, COSV54239859; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IGDCC3 | c.1724C>A p.T575N | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.018); catalogued as COSV60077100; called by muse, mutect2
- NOTCH4 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100900736; called by muse, mutect2, varscan2
- PLCD3 | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs1281210907; called by muse, mutect2
- SCN5A | c.2956C>T p.R986W | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.536); catalogued as rs561547165, COSV61118485; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TRPM5 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768247906, COSV50144952; called by muse, mutect2, varscan2
- NEFM | c.1444G>T p.V482F | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PPP2R1A | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNF6 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TTN | c.22776G>T p.E7592D (on ENST00000591111; = p.E6665D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | PolyPhen benign (0.074); called by muse, mutect2, varscan2
- WDR18 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FER1L6 | c.4587C>A p.L1529= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV67551799; called by muse, mutect2, varscan2
- H3C7 | c.291C>T p.C97= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs1214698895, COSV99769047; called by muse, mutect2, varscan2
- RHOA | c.288A>C p.P96= | Silent (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
